Surgical pathology report (de-identified scan), TCGA case TCGA-28-5220, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5220-01A (Primary Tumor).

[page 1 of 5]
Patient: [REDACTED]

Accession Number: [REDACTED]

Hospital No: [REDACTED]

Pathologist: [REDACTED]

Ordering M.D.: [REDACTED]

Date of Birth: [REDACTED]

Assistant: [REDACTED]

Age/Sex: [REDACTED]

Date of Procedure: [REDACTED]

Copies To: [REDACTED]

Date Received: [REDACTED]

Location: [REDACTED]

TCGA-28-5220

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, RIGHT OCCIPITAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV ✓

B. BRAIN, RIGHT OCCIPITAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

C. BRAIN, RIGHT OCCIPITAL, EXCISIONAL BIOPSY, NCI #1:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 98% of tumor cellularity

D. BRAIN, RIGHT OCCIPITAL, EXCISIONAL BIOPSY, NCI #2:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

E. BRAIN, RIGHT OCCIPITAL, EXCISIONAL BIOPSY, NCI #3:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity

F. BRAIN, RIGHT OCCIPITAL, EXCISIONAL BIOPSY, NCI #4:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity

G. BRAIN, RIGHT OCCIPITAL, EXCISIONAL BIOPSY, NCI #5:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

H. BRAIN, RIGHT OCCIPITAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity

COMMENT:

Patient Case(s): [REDACTED]

Copy For : [REDACTED]
Page 1 of 5

PATIENT NOTIFIED OF RESULTS		
DR.	NURSE	DATE

[page 2 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

[REDACTED]

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to [REDACTED]. Hence, the 80% result in this case suggests the possibility of a relatively diminished response to [REDACTED].

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

[REDACTED] Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme [REDACTED].

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case may predict a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

Right occipital tumor ✓

MICROSCOPIC FINDINGS:

Sections disclose infiltrating glioma composed of minimally pleomorphic population of oval to angulate nuclei associated with numerous mitotic figures, very focal endothelial proliferation and occasional foci of palisading necrosis. The findings are of a glioblastoma multiforme.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
P53	B2	Up to 3% positive
MGMT	B2	Up to 80% (2-3+)
PTEN	B2	Loss (up to 20% of tumor cells positive (3+))

[page 3 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

pMAPK	B2	Up to 90% of tumor nuclei and cytoplasm is positive (2-3+)
Laminin beta-1 (8/411)	B2	Upregulated (2+ focally)
Laminin beta-2 (9/421)	B2	Focally down-regulated (1+)
EGFR by FISH	B2	Pending

GROSS:

A. RIGHT OCCIPITAL TUMOR FS

Labeled with the patient's name, labeled "right occipital tumor frozen", and received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin is a 2.0 x 1.6 x 0.1 cm gray-tan portion of neural tissue. Entirely submitted.

A1. 1

B. RIGHT OCCIPITAL

Labeled with the patient's name, labeled "right occipital", and received in formalin is an 8.0 x 6.0 x 2.0 cm aggregate of gray-tan semi-firm portions of brain ranging from 0.2 to 3.8 cm in greatest dimension. No discrete lesions are identified. Representative sections submitted.

B1-B8. Multiple each

C. RIGHT OCCIPITAL NCI #1

Labeled with the patient's name, labeled "right occipital NCI 1-5" and received in formalin is a 1.1 x 0.7 x 0.2 cm portion of gray-tan soft tissue. Entirely submitted.

C1. 1

D. RIGHT OCCIPITAL NCI #2

Labeled with the patient's name, labeled "right occipital NCI 1-5", and received in formalin is a 1.2 x 1.0 x 0.1 cm portion of gray-tan soft tissue. Entirely submitted.

D1. 1

E. RIGHT OCCIPITAL NCI #3

Labeled with the patient's name, labeled "right occipital NCI 1-5", and received in formalin is a 1.0 x 1.0 x 0.2 cm portion of gray-tan tissue. Entirely submitted.

E1. 1

F. RIGHT OCCIPITAL NCI #4

Labeled with the patient's name, labeled "right occipital NCI 1-5", and received in formalin is a 0.6 x 0.6 x 0.1 cm portion of gray-tan soft tissue. Entirely submitted.

F1. 1

G. RIGHT OCCIPITAL NCI #5

Labeled with the patient's name, labeled "right occipital NCI 1-5", and received in formalin is a 0.6 x 0.4 x 0.2 cm gray-tan portion of soft tissue. Entirely submitted.

G1. 1

H. RIGHT OCCIPITAL CLINICAL TRIAL

Labeled with the patient's name, labeled "right occipital", and received in formalin is a 2.0 x 0.5 x 0.2 cm portion of gray-tan soft tissue. Entirely submitted.

H1. 1

Gross dictated by [REDACTED]

INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN AND TP):

SURGICAL PATHOLOGY REPORT

[page 4 of 5]
PATIENT:

***** Addendum - Please See End of Report *****

ACCESSION #:

A. RIGHT OCCIPITAL, FS + TP:
- High-grade glioma

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[page 5 of 5]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****

ACCESSION #: [REDACTED]

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in BRAIN

Tissue Block: [REDACTED]

RESULTS: POLYSOMY of chromosome 7 (See note below)

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed. The control sample gave expected results.

These studies showed polysomy of chromosome 7 in 70% of the nuclei examined. In brain tumors this signal pattern correlates with an amplified EGFR signal pattern.

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $<40\%$ of the cells.

References:

[REDACTED]

These FISH tests were developed and their performance characteristics determined by [REDACTED] as required by the CLIA [REDACTED] regulations. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file a648b794-a419-4041-a10a-ef418534e592 (TCGA-28-5220.29D77292-B31A-4839-A603-63F355F71368.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).